Somatic mutation profile of cancer-model specimen HCM-BROD-0115-C16-85A (3D Organoid, passage 6; aliquot HCM-BROD-0115-C16-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0115-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 43.5 years (15,886 days).
Specimen HCM-BROD-0115-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 619ffcfe-c532-4ef2-9c69-758c208fd0b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0115-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0115-C16-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35a30b75-96b1-4658-92ed-a887e93d50f1

The open-access MAF lists 134 somatic variants for this specimen: 112 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 19, Frame Shift Del 9, Nonsense Mutation 7, Intron 3, In Frame Del 2, Nonstop Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GAL3ST2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 381/746 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372108744, CM1412990; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 280/538 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1384882995; called by muse, mutect2
- ADAMTS15 | c.1499T>G p.L500R | Missense Mutation (SNP) | VAF 191/416 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs1195459305; called by muse, mutect2, varscan2
- ALOXE3 | c.1061G>A p.W354* | Nonsense Mutation (SNP) | VAF 28/295 reads (9%) | catalogued as rs767046669; called by muse, mutect2, varscan2
- ANO4 | c.169G>T p.D57Y (on ENST00000392977 / NM_001286615.2; = p.D22Y on NM_178826.4) | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs373885901; called by muse, mutect2, varscan2
- CACNA1G | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 139/371 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184328705; called by muse, mutect2, varscan2
- CD209 | c.772T>G p.W258G | Missense Mutation (SNP) | VAF 164/309 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52655421; called by muse, mutect2, varscan2
- CIDEA | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 32/694 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs143259785; called by muse, mutect2
- CNKSR3 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs757670075; called by muse, mutect2, varscan2
- CNTN1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61639394; called by muse, mutect2, varscan2
- CYP27C1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 159/351 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs763255213; called by muse, mutect2, varscan2
- DVL1 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 249/518 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs752206428; called by muse, mutect2, varscan2
- GABRA1 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 264/265 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV50099403; called by muse, mutect2, varscan2
- GSTO1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 77/77 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292504288; called by muse, mutect2, varscan2
- HSPH1 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 120/273 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs368302544, COSV60713590; called by muse, mutect2, varscan2
- IGKV1-5 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 123/367 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1357340047; called by muse, mutect2, varscan2
- LRP2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 134/330 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs147295930, COSV55555420; called by muse, mutect2, varscan2
- NCOR2 | c.2024A>G p.K675R | Missense Mutation (SNP) | VAF 143/290 reads (49%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as rs760401324; called by muse, mutect2, varscan2
- NLRP7 | c.2326G>T p.E776* (on ENST00000340844 / NM_206828.3; = p.E748* on NM_139176.3) | Nonsense Mutation (SNP) | VAF 20/545 reads (4%) | catalogued as COSV60173901; called by muse, mutect2
- NSD3 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 161/320 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs1456616250; called by muse, mutect2, varscan2
- OLFM3 | c.632G>A p.R211H (on ENST00000338858 / NM_001288821.1; = p.R191H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/221 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs776719691, COSV58801848, COSV58804479; called by muse, mutect2, varscan2
- OSM | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 130/594 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.224); catalogued as rs199892388; called by mutect2, varscan2
- PCDHGA5 | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 532/533 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs760966863, COSV54003473; called by muse, mutect2, varscan2
- PNPLA8 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs769232930; called by muse, mutect2, varscan2
- RALBP1 | c.1934C>A p.S645* | Nonsense Mutation (SNP) | VAF 350/528 reads (66%) | catalogued as COSV50034210; called by muse, mutect2, varscan2
- RYR3 | c.10099G>A p.V3367M (on ENST00000389232; = p.V3368M on NM_001036.6) | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761453884, COSV66777080; called by muse, varscan2
- SGSM3 | c.1427C>A p.A476E | Missense Mutation (SNP) | VAF 46/521 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.021); catalogued as rs749504813; called by muse, mutect2
- TMCO6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 269/269 reads (100%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs753691038; called by muse, mutect2, varscan2
- TTN | c.74079G>T p.W24693C (on ENST00000591111; = p.W17269C on NM_003319.4) | Missense Mutation (SNP) | VAF 49/350 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV60195965; called by muse, mutect2, varscan2
- VSX2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777493485, COSV100001830, COSV56217253; called by muse, mutect2
- ZC2HC1C | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 191/392 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs780067829; called by muse, mutect2, varscan2
- ZFHX3 | c.1646C>G p.S549C | Missense Mutation (SNP) | VAF 202/495 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV51741539; called by muse, mutect2, varscan2
- AKNA | c.2774G>A p.G925D | Missense Mutation (SNP) | VAF 41/539 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKNA | c.2773G>T p.G925C | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK2 | c.2177A>G p.K726R | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ANKH | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, varscan2
- ANKRD54 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 61/896 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- AP1G2 | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2
- APLF | c.476_486del p.P159Rfs*6 | Frame Shift Del (DEL) | VAF 89/261 reads (34%) | called by mutect2, pindel, varscan2
- AQP6 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 254/523 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ASH1L | c.7574A>T p.Y2525F (on ENST00000368346 / NM_001366177.2; = p.Y2520F on NM_018489.3) | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BPTF | c.7128T>G p.H2376Q | Missense Mutation (SNP) | VAF 156/637 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP1 | c.2108_2109dup p.N704Lfs*22 | Frame Shift Ins (INS) | VAF 113/633 reads (18%) | called by mutect2, pindel, varscan2
- C19orf81 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 245/526 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CBR1 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 35/513 reads (7%) | called by muse, mutect2
- CCL21 | c.382_398del p.S128Afs*5 | Frame Shift Del (DEL) | VAF 159/168 reads (95%) | called by mutect2, pindel, varscan2
- CCN2 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD99L2 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNR1 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2
- CTNNB1 | c.2346A>C p.*782Yext*4 | Nonstop Mutation (SNP) | VAF 199/199 reads (100%) | called by muse, mutect2, varscan2
- DAAM2 | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- DBP | c.572C>G p.P191R | Missense Mutation (SNP) | VAF 105/287 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOCK10 | c.6236C>A p.A2079D | Missense Mutation (SNP) | VAF 128/317 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DSCAM | c.4896_4909del p.K1632Nfs*5 | Frame Shift Del (DEL) | VAF 31/244 reads (13%) | called by mutect2, pindel, varscan2
- DYRK3 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDARADD | c.430_435del p.S144_K145del (on ENST00000334232 / NM_145861.4; = p.S134_K135del on NM_080738.4) | In Frame Del (DEL) | VAF 125/384 reads (33%) | called by mutect2, pindel, varscan2
- EFR3A | c.1987A>G p.N663D | Missense Mutation (SNP) | VAF 48/560 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.036); called by muse, mutect2
- EIF4E1B | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 134/391 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- EPB41L1 | c.56_72del p.P19Rfs*22 | Frame Shift Del (DEL) | VAF 305/548 reads (56%) | called by pindel, varscan2
- FABP12 | c.247A>C p.S83R | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FAT4 | c.2642_2688del p.I881Nfs*25 | Frame Shift Del (DEL) | VAF 88/301 reads (29%) | called by mutect2, pindel, varscan2
- GCN1 | c.1404G>T p.L468F | Missense Mutation (SNP) | VAF 22/435 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- HDGF | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 178/610 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.048); called by muse, mutect2
- IGDCC4 | c.1973T>C p.I658T | Missense Mutation (SNP) | VAF 198/622 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- IL5RA | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 218/218 reads (100%) | called by muse, mutect2, varscan2
- ISY1-RAB43 | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 88/394 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2
- LAMA3 | c.7838C>A p.T2613N (on ENST00000313654 / NM_198129.4; = p.T1004N on NM_000227.6) | Missense Mutation (SNP) | VAF 25/484 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- LHX1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 680/1121 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LIMCH1 | c.1272A>C p.R424S | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LRP8 | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 23/657 reads (4%) | called by muse, mutect2
- MAZ | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 132/412 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MCOLN2 | c.879T>G p.F293L | Missense Mutation (SNP) | VAF 284/284 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MMP12 | c.1232A>T p.D411V | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MPEG1 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 201/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPP3 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 209/606 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.36962A>G p.E12321G | Missense Mutation (SNP) | VAF 174/363 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MXRA5 | c.2218G>C p.G740R | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2
- NASP | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NUP214 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 128/648 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- OLFML1 | c.1099A>G p.S367G | Missense Mutation (SNP) | VAF 116/389 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- OLFML2B | c.1844_1864del p.Q615_F622delinsL | In Frame Del (DEL) | VAF 90/669 reads (13%) | called by mutect2, pindel, varscan2
- OR1J4 | c.887A>T p.D296V | Missense Mutation (SNP) | VAF 35/586 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- OSBPL1A | c.207+1G>A p.X69_splice | Splice Site (SNP) | VAF 101/198 reads (51%) | called by muse, mutect2, varscan2
- P2RY10 | c.401T>C p.F134S | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PBRM1 | c.2972A>T p.K991I | Missense Mutation (SNP) | VAF 143/144 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PNPLA6 | c.2094_2097+1del | Frame Shift Del (DEL) | VAF 86/261 reads (33%) | called by mutect2, pindel, varscan2
- PTGES3L-AARSD1 | c.1468C>G p.P490A (on ENST00000421990 / NM_001136042.2; = p.P472A on NM_025267.3) | Missense Mutation (SNP) | VAF 19/587 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- PTGS1 | c.1369A>C p.M457L | Missense Mutation (SNP) | VAF 183/563 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTK2B | c.1154A>G p.E385G | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- RANBP2 | c.6144G>T p.E2048D | Missense Mutation (SNP) | VAF 162/483 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RC3H2 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 379/598 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RRBP1 | c.3592A>G p.T1198A (on ENST00000377813 / NM_001365613.2; = p.T765A on NM_004587.3) | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.395); called by muse, mutect2
- S1PR3 | c.445A>C p.N149H | Missense Mutation (SNP) | VAF 237/569 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SAMD3 | c.893C>A p.T298K | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2
- SH3YL1 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 107/254 reads (42%) | called by muse, mutect2, varscan2
- SLC12A5 | c.302A>C p.H101P (on ENST00000454036 / NM_001134771.2; = p.H78P on NM_020708.5) | Missense Mutation (SNP) | VAF 20/531 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2
- SLC18A1 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 159/312 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC27A1 | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2
- SPTA1 | c.3736G>T p.A1246S | Missense Mutation (SNP) | VAF 281/432 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SYT16 | c.376T>A p.W126R | Missense Mutation (SNP) | VAF 17/513 reads (3%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2
- TACC2 | c.5110del p.E1704Kfs*8 | Frame Shift Del (DEL) | VAF 122/463 reads (26%) | called by mutect2, pindel, varscan2
- TBC1D22B | c.274_287del p.V92Cfs*37 | Frame Shift Del (DEL) | VAF 104/333 reads (31%) | called by mutect2, pindel, varscan2
- TDRKH | c.1551T>G p.D517E | Missense Mutation (SNP) | VAF 89/426 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS2 | c.3078C>G p.S1026R (on ENST00000314250 / NM_170754.4; = p.S1036R on NM_015319.2) | Missense Mutation (SNP) | VAF 340/733 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TREX2 | c.210del p.I70Mfs*25 (on ENST00000334497; = p.I27Mfs*25 on NM_080701.3) | Frame Shift Del (DEL) | VAF 60/417 reads (14%) | called by mutect2, pindel, varscan2
- TTLL11 | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 378/554 reads (68%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); called by mutect2, varscan2
- TUFT1 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- UNC79 | c.1395T>G p.H465Q (on ENST00000393151 / NM_001346218.2; = p.H288Q on NM_020818.5) | Missense Mutation (SNP) | VAF 166/245 reads (68%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WRAP73 | c.1363C>G p.Q455E | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF131 | c.1550C>A p.P517Q (on ENST00000509156 / NM_001330707.2; = p.P483Q on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF316 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 31/980 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF804A | c.3275C>T p.S1092F | Missense Mutation (SNP) | VAF 175/318 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF18 | c.156G>A p.P52= | Silent (SNP) | VAF 302/624 reads (48%) | called by muse, mutect2
- CYTL1 | c.174G>T p.L58= | Silent (SNP) | VAF 117/392 reads (30%) | called by muse, mutect2, varscan2
- EPB41L1 | c.78C>T p.A26= | Silent (SNP) | VAF 352/560 reads (63%) | catalogued as rs372761608; called by muse, varscan2
- EVC | c.2814C>T p.P938= | Silent (SNP) | VAF 88/391 reads (23%) | called by muse, mutect2, varscan2
- FCRLB | c.192C>A p.G64= | Silent (SNP) | VAF 191/721 reads (26%) | catalogued as rs777301346, COSV100396075; called by muse, mutect2, varscan2
- FSIP2 | c.1179T>C p.N393= | Silent (SNP) | VAF 79/196 reads (40%) | called by muse, mutect2, varscan2
- IQCA1L | c.2407T>C p.L803= | Silent (SNP) | VAF 212/405 reads (52%) | called by muse, mutect2, varscan2
- IQCA1L | c.1980G>T p.L660= | Silent (SNP) | VAF 202/420 reads (48%) | called by muse, mutect2, varscan2
- ISY1-RAB43 | c.63A>G p.E21= | Silent (SNP) | VAF 88/394 reads (22%) | catalogued as rs1276849268; called by muse, mutect2
- KMT2D | c.4932C>T p.D1644= | Silent (SNP) | VAF 150/336 reads (45%) | called by muse, mutect2, varscan2
- LAMA3 | c.7839T>G p.T2613= (on ENST00000313654 / NM_198129.4; = p.T1004= on NM_000227.6) | Silent (SNP) | VAF 25/482 reads (5%) | called by muse, mutect2
- LNX2 | c.963C>T p.G321= | Silent (SNP) | VAF 234/403 reads (58%) | called by muse, mutect2, varscan2
- MUC16 | c.312G>T p.S104= | Silent (SNP) | VAF 164/341 reads (48%) | catalogued as rs375785587; called by muse, varscan2
- PDE4A | c.945A>G p.R315= (on ENST00000380702 / NM_001111307.2; = p.R76= on NM_006202.3) | Silent (SNP) | VAF 180/418 reads (43%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.2121G>A p.P707= | Silent (SNP) | VAF 254/521 reads (49%) | called by muse, mutect2, varscan2
- PLP1 | c.132A>G p.E44= | Silent (SNP) | VAF 183/265 reads (69%) | called by muse, mutect2, varscan2
- POTEE | c.2841C>T p.V947= | Silent (SNP) | VAF 248/1608 reads (15%) | called by muse, mutect2
- PPP4R1 | c.1416T>G p.L472= (on ENST00000400556 / NM_001042388.3; = p.L455= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 400/647 reads (62%) | called by muse, mutect2
- SFTPA2 | c.138G>A p.G46= | Silent (SNP) | VAF 157/357 reads (44%) | catalogued as rs746354270; called by muse, mutect2, varscan2
- CCDC74B | c.295+305G>A | Intron (SNP) | VAF 202/402 reads (50%) | catalogued as rs1394222364; called by muse, mutect2, varscan2
- KCNQ5 | c.1248-3571_1248-3543del | Intron (DEL) | VAF 42/50 reads (84%) | called by mutect2, pindel, varscan2
- NKX6-3 | c.553-562C>G | Intron (SNP) | VAF 246/504 reads (49%) | called by muse, mutect2, varscan2
